Somatic mutation profile of tumor specimen PCProject_0557_T2_WES (aliquot PCProject_0557_T2_WES_1) from CMI case PCProject_0557, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.0 years (21,924 days).
Specimen PCProject_0557_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be0c5d47-434d-4cc7-9f5d-56f20c10103c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0557_SALIVA (Saliva), aliquot PCProject_0557_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb38f89-0205-4cdf-a20e-e588ef5ed778

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Intron 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 244/839 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53730133; called by muse, mutect2, varscan2
- ASB18 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs1004290536; called by muse, mutect2
- ATG13 | c.1400A>G p.Y467C (on ENST00000359513 / NM_001346321.1; = p.Y430C on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371908542; called by muse, mutect2, varscan2
- ATP2B2 | c.2974G>A p.V992I (on ENST00000352432; = p.V958I on NM_001683.5) | Missense Mutation (SNP) | VAF 490/2008 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs765963921, COSV59495098; called by muse, mutect2, varscan2
- DNAH5 | c.8770G>A p.A2924T | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs748993870, COSV54205191; called by muse, mutect2, varscan2
- GPR139 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 78/665 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs146922265; called by muse, mutect2, varscan2
- MYO3A | c.3938G>A p.R1313H | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs142853143, COSV56319295; called by muse, mutect2, varscan2
- PLA2G4E | c.1539C>A p.Y513* | Nonsense Mutation (SNP) | VAF 71/356 reads (20%) | catalogued as COSV68149239; called by muse, mutect2, varscan2
- SOBP | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 180/688 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1484501026; called by muse, mutect2, varscan2
- TTN | c.17360C>T p.P5787L (on ENST00000591111; = p.P4860L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/238 reads (25%) | PolyPhen benign (0.01); catalogued as COSV100602153; called by muse, mutect2, varscan2
- UNC13A | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764119582, COSV53189928; called by muse, mutect2, varscan2
- ZNF521 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV64127656; called by muse, mutect2, varscan2
- ADAM21 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, varscan2
- BAALC | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 345/1758 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IGHV3-43 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NCEH1 | c.602A>G p.D201G (on ENST00000538775; = p.D161G on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PPP2R2B | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEMA5A | c.3086A>T p.D1029V | Missense Mutation (SNP) | VAF 39/446 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.15); called by muse, mutect2
- ADAMTS19 | c.630G>C p.T210= | Silent (SNP) | VAF 42/623 reads (7%) | catalogued as rs773298842; called by muse, mutect2
- ATP7B | c.2127C>T p.L709= | Silent (SNP) | VAF 119/707 reads (17%) | catalogued as rs780843377, COSV99666656; called by muse, mutect2, varscan2
- DDX17 | c.1287A>G p.R429= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1391201328; called by muse, mutect2, varscan2
- IRF4 | c.1122C>T p.H374= | Silent (SNP) | VAF 89/442 reads (20%) | catalogued as rs760994228, COSV66704965; called by muse, mutect2, varscan2
- ITPK1 | c.1068C>T p.S356= | Silent (SNP) | VAF 162/2164 reads (7%) | catalogued as rs753632511, COSV50897610; called by muse, mutect2
- MYLK | c.525A>G p.G175= | Silent (SNP) | VAF 173/1233 reads (14%) | called by muse, mutect2, varscan2
- GRSF1 | c.357+68_357+89del | Intron (DEL) | VAF 190/1032 reads (18%) | called by mutect2, pindel
- GUCY1B2 | n.886C>T | RNA (SNP) | VAF 28/117 reads (24%) | catalogued as rs866836856; called by muse, mutect2, varscan2
